Somatic mutation profile of tumor specimen C3L-09778-03 (aliquot CPT0516120006) from CPTAC case C3L-09778, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.6 years (24,677 days).
Specimen C3L-09778-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127f497e-43dc-418c-bc6e-297c9ec02428.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09778-31 (Blood Derived Normal), aliquot CPT0516250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7653b8ae-4e7f-478e-8621-e3502422e9d6

The open-access MAF lists 294 somatic variants for this specimen: 221 protein-altering or splice-affecting, 58 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 58, Nonsense Mutation 18, Intron 7, 5'UTR 4, Frame Shift Ins 4, Splice Site 3, Frame Shift Del 3, 3'UTR 3, Nonstop Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPRL3 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 150/296 reads (51%) | catalogued as rs1567152003; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.254del p.P85Lfs*38 | Frame Shift Del (DEL) | VAF 150/510 reads (29%) | catalogued as rs1064793279, COSV53087170; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS8 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs775007123, COSV99961613; called by muse, mutect2, varscan2
- ADGRB3 | c.3140T>G p.L1047R | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53253255, COSV53258799; called by muse, mutect2, varscan2
- ADGRD2 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 165/307 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs747013058; called by muse, mutect2, varscan2
- AIM2 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100931077, COSV63701478; called by muse, mutect2, varscan2
- ANGPTL5 | c.193T>C p.C65R | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1256742808; called by muse, mutect2, varscan2
- APBA1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 150/448 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV55231083; called by muse, mutect2, varscan2
- APOB | c.12835G>C p.E4279Q | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV51928518; called by muse, mutect2, varscan2
- ARHGAP15 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99710092; called by muse, mutect2, varscan2
- ASB2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs941423674, COSV100279542, COSV100279677; called by muse, mutect2, varscan2
- ATP9A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV100125492; called by muse, mutect2
- BRAF | c.2132G>A p.R711Q (on ENST00000288602 / NM_001374244.1; = p.R671Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs397507485, COSV56226275, COSV99967384; called by muse, mutect2, varscan2
- CNTN6 | c.1005G>T p.L335F | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1399752873; called by muse, mutect2, varscan2
- CPNE8 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV100503720, COSV58850235; called by muse, mutect2, varscan2
- DDI1 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 99/299 reads (33%) | catalogued as rs142068013; called by muse, mutect2, varscan2
- DNAH1 | c.8722G>A p.D2908N | Missense Mutation (SNP) | VAF 112/434 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs573387592; called by muse, mutect2, varscan2
- DST | c.17624G>T p.R5875L (on ENST00000361203 / NM_001374722.1; = p.R3572L on NM_015548.5) | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55038553, COSV55040516; called by muse, mutect2, varscan2
- DTX2 | c.714T>G p.F238L | Missense Mutation (SNP) | VAF 163/621 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1431112399; called by muse, mutect2, varscan2
- FAM171B | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV59007471, COSV59009953; called by muse, mutect2
- FAM200B | c.320T>G p.L107* | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | catalogued as rs1270258545; called by muse, mutect2, varscan2
- FANCD2 | c.1528A>C p.N510H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV55034774; called by muse, mutect2, varscan2
- FOXR2 | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 97/174 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59259868; called by muse, mutect2, varscan2
- FZD10 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 73/464 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566096665, COSV57474346; called by muse, mutect2, varscan2
- GIMAP1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 148/578 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.261); catalogued as COSV56187257; called by muse, mutect2, varscan2
- GPR84 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868793018, COSV57210290; called by mutect2, varscan2
- HBP1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs1452649288, COSV56018019; called by muse, mutect2, varscan2
- HEATR1 | c.4377G>C p.Q1459H | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63979982; called by muse, mutect2, varscan2
- HFM1 | c.2768T>C p.L923P | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54038589; called by muse, mutect2, varscan2
- IGKV3D-11 | c.318T>G p.Y106* | Nonsense Mutation (SNP) | VAF 72/287 reads (25%) | catalogued as rs555588989; called by muse, mutect2, varscan2
- IRS1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs1412843577; called by muse, mutect2
- KCNH1 | c.236C>G p.T79R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs751940352; called by muse, mutect2
- KMT2E | c.2518C>G p.Q840E | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.039); catalogued as COSV57572718; called by muse, mutect2, varscan2
- LIMS2 | c.424C>T p.R142W (on ENST00000355119 / NM_001161403.3; = p.R166W on NM_017980.4) | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs780800196, COSV55757598; called by muse, varscan2
- LONRF2 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV66540613; called by muse, mutect2, varscan2
- LOXHD1 | c.3659A>C p.K1220T | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56063150, COSV56074005; called by muse, mutect2, varscan2
- LRP2 | c.12193C>T p.R4065* | Nonsense Mutation (SNP) | VAF 40/208 reads (19%) | catalogued as rs1228784624, COSV55545838; called by muse, mutect2, varscan2
- MAD1L1 | c.1160G>C p.R387P | Missense Mutation (SNP) | VAF 135/430 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV56236783; called by muse, mutect2, varscan2
- MAP2 | c.4898A>G p.K1633R | Missense Mutation (SNP) | VAF 103/472 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV52304258; called by muse, mutect2, varscan2
- MOK | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1472224633; called by muse, mutect2, varscan2
- MUC4 | c.15505C>G p.L5169V (on ENST00000463781 / NM_018406.7; = p.L933V on NM_004532.6) | Missense Mutation (SNP) | VAF 105/395 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs567918321; called by muse, mutect2, varscan2
- MYO9B | c.5588C>T p.P1863L | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487661795; called by muse, mutect2, varscan2
- NOTCH4 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 88/507 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs777675400; called by muse, mutect2, varscan2
- OR1S1 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748421748, COSV58706349, COSV58708943; called by muse, mutect2, varscan2
- OR4C12 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV58860982, COSV58861117; called by muse, mutect2, varscan2
- OR8H3 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, varscan2
- PBX3 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 141/520 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.548); catalogued as rs1331800511; called by muse, mutect2, varscan2
- PCDH1 | c.3713G>C p.*1238Sext*117 | Nonstop Mutation (SNP) | VAF 32/227 reads (14%) | catalogued as COSV54618153; called by muse, mutect2, varscan2
- PCDHGA6 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99538910; called by muse, mutect2, varscan2
- PELP1 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 204/419 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1178449857, COSV99036317; called by muse, mutect2, varscan2
- PEX6 | c.2927A>C p.K976T | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV55104668; called by muse, mutect2, varscan2
- PI4KA | c.3803C>T p.S1268F | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99747289; called by muse, mutect2, varscan2
- PLEC | c.6209G>A p.S2070N (on ENST00000322810 / NM_201380.4; = p.S1960N on NM_000445.5) | Missense Mutation (SNP) | VAF 183/440 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.047); catalogued as rs1288160719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLVAP | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs151286294; called by muse, mutect2, varscan2
- POR | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 43/346 reads (12%) | catalogued as rs1311906406; called by muse, mutect2, varscan2
- PRKN | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs761430731, COSV58215260; called by muse, mutect2, varscan2
- PTPA | c.943G>A p.A315T (on ENST00000337738 / NM_178001.2; = p.A280T on NM_021131.5) | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV61234969; called by muse, mutect2, varscan2
- RBP3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs782358403; called by muse, mutect2, varscan2
- RFTN1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111844340, COSV61918876; called by muse, mutect2, varscan2
- RFX5 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs773920954, COSV51841584; called by muse, mutect2, varscan2
- RNASEL | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV62376830; called by muse, varscan2
- RUBCNL | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100528828; called by muse, mutect2
- SCG2 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV59539990; called by muse, mutect2, varscan2
- SHANK2 | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 127/403 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs922746107; called by muse, mutect2, varscan2
- SLC8A1 | c.1219A>T p.S407C | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1214676125; called by muse, mutect2, varscan2
- SLITRK2 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59422987; called by muse, mutect2, varscan2
- SMTNL2 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 362/649 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1199979962; called by muse, mutect2, varscan2
- SPATA17 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV65126197; called by muse, mutect2, varscan2
- STEAP1B | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 36/382 reads (9%) | catalogued as rs199876235; called by muse, mutect2
- SYT16 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761346026, COSV70855321; called by muse, mutect2, varscan2
- TLL1 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV50276476; called by muse, mutect2, varscan2
- TNIK | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs774179426, COSV52674109; called by muse, mutect2, varscan2
- TNXB | c.10432A>G p.K3478E (on ENST00000647633; = p.K3231E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/606 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1370169851, COSV100926718; called by muse, mutect2, varscan2
- TTBK1 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 95/674 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs528510058, COSV52490334; called by muse, mutect2, varscan2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- UQCRC1 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52552256; called by muse, mutect2, varscan2
- VGLL2 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 166/570 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs762916748, COSV58310265; called by muse, mutect2, varscan2
- WDR49 | c.898+1G>A p.X300_splice (on ENST00000308378 / NM_001366158.1; = p.X641_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/85 reads (27%) | catalogued as rs1231890150, COSV100391380; called by muse, mutect2, varscan2
- WRNIP1 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 171/727 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.011); catalogued as rs777548809; called by muse, mutect2, varscan2
- ZEB1 | c.2562A>C p.Q854H | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58036483, COSV58048168; called by muse, mutect2, varscan2
- ZGRF1 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV58412126; called by muse, mutect2, varscan2
- ZNF775 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 18/589 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs986266263; called by muse, mutect2
- ZNF804B | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV60853182; called by muse, mutect2
- ZNF831 | c.4373C>G p.S1458* | Nonsense Mutation (SNP) | VAF 161/471 reads (34%) | catalogued as COSV64042483; called by muse, mutect2, varscan2
- AC098582.1 | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ADGRL4 | c.1979T>A p.I660N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADRB2 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFM | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKR7A2 | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ALMS1 | c.8344G>C p.D2782H | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- AMFR | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 75/195 reads (38%) | called by muse, varscan2
- ANGPTL2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 262/501 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4E1 | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ARHGAP5 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARNTL2 | c.1849T>G p.L617V | Missense Mutation (SNP) | VAF 78/332 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ARSG | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRX | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 86/160 reads (54%) | called by muse, mutect2, varscan2
- BANK1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BICRAL | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- C14orf180 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- C17orf50 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 66/495 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- C2orf16 | c.1826C>G p.P609R | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C9orf40 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CACNA1A | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CALCRL | c.302T>G p.V101G | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CCDC136 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC39 | c.254_255insG p.H85Qfs*3 | Frame Shift Ins (INS) | VAF 57/213 reads (27%) | called by mutect2, pindel, varscan2
- CCDC80 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 107/435 reads (25%) | called by muse, mutect2, varscan2
- CDKL5 | c.1887G>C p.L629F | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- CHRNG | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CLIP1 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CNKSR2 | c.3011C>G p.T1004S | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COQ6 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPOX | c.197C>G p.S66W | Missense Mutation (SNP) | VAF 88/584 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- CPS1 | c.4461T>G p.S1487R | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CRIM1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CTTNBP2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 15/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DACH1 | c.1468G>C p.D490H (on ENST00000619232 / NM_001366712.1; = p.D438H on NM_080759.6) | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DCBLD2 | c.1983A>C p.E661D | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCDC1 | c.4694T>A p.L1565Q (on ENST00000597505 / NM_001367979.1; = p.L672Q on NM_020869.3) | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DCDC1 | c.78A>C p.E26D | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DICER1 | c.1519A>G p.K507E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- DLG4 | c.1870A>C p.K624Q (on ENST00000399506 / NM_001321075.3; = p.K667Q on NM_001365.4) | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- DNAAF4 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- DQX1 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 80/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DSEL | c.2738C>A p.A913D | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- E2F8 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 134/475 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- EEF1G | c.237G>C p.V79= | Splice Region (SNP) | VAF 36/261 reads (14%) | called by muse, mutect2, varscan2
- ELN | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FBXL12 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FEM1C | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- FHL2 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 71/632 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FIGN | c.2116C>G p.H706D | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FLNC | c.3936C>G p.Y1312* | Nonsense Mutation (SNP) | VAF 64/451 reads (14%) | called by muse, mutect2, varscan2
- FLT4 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2
- GABRB3 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GAD1 | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBX1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 134/513 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GCN1 | c.4189G>A p.A1397T | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA8M | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- GPR176 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- HECTD4 | c.7996C>G p.Q2666E | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2
- HMGN1 | c.15+1G>C p.X5_splice | Splice Site (SNP) | VAF 156/353 reads (44%) | called by muse, mutect2, varscan2
- HPS4 | c.198C>G p.D66E | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGKV2-24 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IWS1 | c.1610dup p.S538Efs*17 | Frame Shift Ins (INS) | VAF 62/321 reads (19%) | called by mutect2, pindel, varscan2
- JKAMP | c.323C>A p.A108E (on ENST00000554271 / NM_001284201.1; = p.A94E on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF21A | c.4151G>A p.G1384E (on ENST00000361418 / NM_001378440.1; = p.G1371E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- LAMC2 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LCTL | c.1427T>C p.V476A | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- LILRB3 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 109/678 reads (16%) | called by muse, mutect2, varscan2
- LIMD1 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- LIPA | c.664C>G p.H222D | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC7 | c.2314C>T p.L772F (on ENST00000651989 / NM_001370785.2; = p.L739F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MAGI2 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTM1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MYH2 | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MYO16 | c.4195G>A p.A1399T | Missense Mutation (SNP) | VAF 134/523 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MYT1 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 64/390 reads (16%) | called by muse, mutect2, varscan2
- NBR1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NEK10 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NFXL1 | c.632A>T p.D211V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2
- NOTCH1 | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 47/381 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR4C3 | c.180_181del p.L61Gfs*7 | Frame Shift Del (DEL) | VAF 30/258 reads (12%) | called by mutect2, pindel, varscan2
- OR6K6 | c.97A>G p.N33D (on ENST00000368144; = p.N9D on NM_001005184.1) | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2
- OR8J2 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OSBPL10 | c.1455G>C p.E485D | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSMR | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); called by muse, mutect2
- PDE10A | c.2236C>G p.P746A | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLCH2 | c.4078C>T p.Q1360* | Nonsense Mutation (SNP) | VAF 20/692 reads (3%) | called by muse, mutect2
- PLCL1 | c.2928A>T p.Q976H | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPFIBP1 | c.215_228del p.C72Ffs*8 | Frame Shift Del (DEL) | VAF 63/335 reads (19%) | called by mutect2, pindel, varscan2
- PSMD2 | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PTPN23 | c.3431C>G p.T1144S | Missense Mutation (SNP) | VAF 155/579 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRR | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAET1E | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2
- RAG1 | c.1158dup p.V387Cfs*4 | Frame Shift Ins (INS) | VAF 72/352 reads (20%) | called by mutect2, pindel, varscan2
- RAPH1 | c.762G>C p.E254D (on ENST00000319170 / NM_213589.3; = p.E306D on NM_203365.4) | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RERG | c.202A>C p.I68L | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RMND1 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- RNF207 | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RSF1 | c.3182A>T p.K1061I | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA6C | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 128/449 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SKOR1 | c.2407_2407+20del p.X803_splice | Splice Site (DEL) | VAF 53/412 reads (13%) | called by mutect2, pindel
- SLC10A2 | c.386T>A p.M129K | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SMC3 | c.3528G>T p.R1176S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMURF1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- SNX13 | c.1931dup p.D645Gfs*13 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- SOWAHB | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SPATA20 | c.569C>T p.T190I (on ENST00000356488 / NM_001258372.1; = p.T206I on NM_022827.4) | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.484); called by muse, mutect2
- SPTA1 | c.1167G>C p.K389N | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SRGAP3 | c.2858A>C p.K953T | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SYT1 | c.1128A>C p.K376N | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCHH | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 180/608 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TCHH | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 130/454 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TEAD4 | c.853T>A p.F285I | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TEX13C | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- TIMP4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, varscan2
- TMPRSS11D | c.321A>T p.Q107H | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TPK1 | c.633T>G p.F211L | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM23 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- TUBB1 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UBQLN2 | c.454_477del p.A152_L159del | In Frame Del (DEL) | VAF 62/301 reads (21%) | called by mutect2, pindel, varscan2
- UGT2B10 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- UHRF2 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WAPL | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- WDR7 | c.3336A>C p.K1112N | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WDR70 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 63/814 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- XAB2 | c.699C>A p.D233E | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YIPF7 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H11B | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 68/610 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF334 | c.817A>C p.T273P | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ZNF385B | c.771T>G p.S257R | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF620 | c.321A>C p.K107N | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF644 | c.2614C>G p.Q872E | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF800 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- ZNF804B | c.793T>C p.C265R | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- ZNF853 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 167/685 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, varscan2
- ZXDA | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 173/357 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZYG11B | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- A2ML1 | c.3609C>T p.A1203= | Silent (SNP) | VAF 48/312 reads (15%) | called by muse, mutect2, varscan2
- ACE | c.3114G>A p.L1038= | Silent (SNP) | VAF 12/315 reads (4%) | called by muse, mutect2
- AFF2 | c.1119T>G p.T373= | Silent (SNP) | VAF 79/183 reads (43%) | catalogued as COSV54009481; called by muse, mutect2, varscan2
- AGRN | c.3393C>G p.T1131= | Silent (SNP) | VAF 42/160 reads (26%) | called by muse, mutect2, varscan2
- ANO3 | c.1500T>G p.T500= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs1473007257; called by muse, mutect2, varscan2
- ATG4C | c.1203C>T p.I401= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- ATXN2 | c.3588G>A p.A1196= (on ENST00000550104; = p.A1036= on NM_002973.4) | Silent (SNP) | VAF 123/431 reads (29%) | catalogued as rs778832050, COSV100373973; called by muse, mutect2, varscan2
- B3GALT2 | c.1035G>C p.G345= | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- C1S | c.1608A>G p.K536= | Silent (SNP) | VAF 113/409 reads (28%) | called by muse, mutect2, varscan2
- CAMK1 | c.936G>A p.V312= | Silent (SNP) | VAF 29/253 reads (11%) | catalogued as rs771152728; called by muse, varscan2
- CIDEB | c.648C>T p.L216= | Silent (SNP) | VAF 32/317 reads (10%) | catalogued as COSV99350547; called by muse, mutect2, varscan2
- CLCA2 | c.2082T>A p.S694= | Silent (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- EHMT1 | c.3759C>G p.L1253= | Silent (SNP) | VAF 73/534 reads (14%) | catalogued as rs762125127; called by muse, mutect2, varscan2
- FGF22 | c.222G>T p.L74= | Silent (SNP) | VAF 72/212 reads (34%) | called by muse, mutect2, varscan2
- HAUS5 | c.1901G>A p.*634= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as COSV99177746; called by muse, mutect2, varscan2
- HCN2 | c.1590C>T p.I530= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as rs772634568, COSV52114253; called by muse, mutect2, varscan2
- HELZ2 | c.3456G>A p.S1152= (on ENST00000467148 / NM_001037335.2; = p.S583= on NM_033405.3) | Silent (SNP) | VAF 169/896 reads (19%) | catalogued as rs774721417; called by muse, mutect2, varscan2
- HEXIM1 | c.543A>G p.K181= | Silent (SNP) | VAF 99/284 reads (35%) | catalogued as rs1318021793; called by muse, mutect2, varscan2
- HTATIP2 | c.633G>A p.L211= | Silent (SNP) | VAF 81/374 reads (22%) | catalogued as rs779185313; called by muse, mutect2, varscan2
- KHNYN | c.1557G>A p.R519= | Silent (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- KIF21A | c.3870T>G p.L1290= (on ENST00000361418 / NM_001378440.1; = p.L1277= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- KLHL25 | c.282C>T p.H94= | Silent (SNP) | VAF 109/407 reads (27%) | catalogued as rs749741776; called by muse, mutect2, varscan2
- KMT2A | c.6886T>C p.L2296= | Silent (SNP) | VAF 81/218 reads (37%) | called by muse, mutect2, varscan2
- LRFN3 | c.1068C>T p.T356= | Silent (SNP) | VAF 155/465 reads (33%) | catalogued as rs777885478; called by muse, mutect2, varscan2
- MACC1 | c.177T>C p.N59= | Silent (SNP) | VAF 55/238 reads (23%) | called by muse, mutect2, varscan2
- MACF1 | c.15636A>G p.K5212= (on ENST00000372915; = p.K3145= on NM_012090.5) | Silent (SNP) | VAF 53/263 reads (20%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.1278A>G p.E426= | Silent (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2
- MUC16 | c.21183T>C p.T7061= | Silent (SNP) | VAF 79/225 reads (35%) | catalogued as COSV101199290, COSV67467087; called by muse, mutect2, varscan2
- NEFM | c.579G>A p.A193= | Silent (SNP) | VAF 145/413 reads (35%) | called by muse, mutect2, varscan2
- NIBAN1 | c.1662G>A p.L554= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- NKD2 | c.1008C>T p.G336= | Silent (SNP) | VAF 164/851 reads (19%) | called by muse, mutect2, varscan2
- NKX2-5 | c.210C>A p.R70= | Silent (SNP) | VAF 262/588 reads (45%) | called by muse, mutect2, varscan2
- NLGN3 | c.804G>T p.V268= (on ENST00000358741 / NM_181303.2; = p.V248= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 134/279 reads (48%) | called by muse, mutect2, varscan2
- OR52E1 | c.528T>G p.T176= | Silent (SNP) | VAF 94/283 reads (33%) | called by muse, mutect2, varscan2
- OSBPL6 | c.420C>T p.V140= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- PCDHA12 | c.2100C>G p.L700= | Silent (SNP) | VAF 183/372 reads (49%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1668G>T p.L556= | Silent (SNP) | VAF 255/413 reads (62%) | called by muse, mutect2, varscan2
- PDE4D | c.1782G>A p.V594= (on ENST00000340635 / NM_001104631.2; = p.V458= on NM_006203.4) | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs376924138; called by muse, mutect2, varscan2
- PLXNB1 | c.405G>A p.E135= | Silent (SNP) | VAF 89/509 reads (17%) | called by muse, mutect2, varscan2
- PRL | c.333G>C p.L111= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as COSV100123262, COSV60592996; called by muse, mutect2, varscan2
- PTPRU | c.1725C>T p.F575= | Silent (SNP) | VAF 68/244 reads (28%) | catalogued as rs187052302; called by muse, mutect2, varscan2
- RASAL3 | c.1920G>T p.L640= | Silent (SNP) | VAF 55/307 reads (18%) | called by muse, mutect2, varscan2
- RASGRF1 | c.3624G>A p.T1208= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as rs749987303, COSV67250794; called by muse, mutect2, varscan2
- RICTOR | c.2976T>G p.A992= | Silent (SNP) | VAF 71/340 reads (21%) | called by muse, mutect2, varscan2
- RSPO2 | c.378T>C p.D126= | Silent (SNP) | VAF 52/192 reads (27%) | called by muse, mutect2, varscan2
- SGCZ | c.150C>T p.Y50= | Silent (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- SHC4 | c.918C>T p.Y306= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs553983973, COSV60116557; called by muse, mutect2
- SLC16A7 | c.951C>T p.F317= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs1490683240; called by muse, mutect2, varscan2
- SLC5A12 | c.57C>T p.F19= | Silent (SNP) | VAF 69/313 reads (22%) | catalogued as rs764786158, COSV54823759; called by muse, mutect2, varscan2
- SMURF1 | c.2133G>C p.L711= | Silent (SNP) | VAF 105/394 reads (27%) | called by muse, mutect2, varscan2
- SUSD6 | c.792A>T p.S264= | Silent (SNP) | VAF 124/496 reads (25%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.2481C>T p.I827= | Silent (SNP) | VAF 127/549 reads (23%) | called by muse, mutect2, varscan2
- TANC2 | c.159C>T p.S53= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as rs1423648150, COSV67333839; called by muse, varscan2
- TRIM77 | c.714T>C p.C238= | Silent (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- TRPM1 | c.372G>A p.L124= | Silent (SNP) | VAF 40/482 reads (8%) | called by muse, mutect2
- TTN | c.57531C>T p.V19177= (on ENST00000591111; = p.V11753= on NM_003319.4) | Silent (SNP) | VAF 31/299 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.30285A>G p.K10095= (on ENST00000591111; = p.K9168= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs745578231; called by muse, mutect2, varscan2
- TUT7 | c.432C>T p.D144= | Silent (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- ALG10B | c.*8020G>C | 3'UTR (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-60G>A | Intron (SNP) | VAF 80/282 reads (28%) | catalogued as rs781437535; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943423 G>C | 3'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- C2CD6 | c.1582-3410G>C | Intron (SNP) | VAF 10/320 reads (3%) | called by muse, mutect2
- FOXA1 | c.-229C>G | 5'UTR (SNP) | VAF 37/138 reads (27%) | catalogued as rs1448679398; called by muse, mutect2, varscan2
- GOLGA6L2 | c.*59C>A | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- HDHD5-AS1 | n.440-40del | Intron (DEL) | VAF 74/225 reads (33%) | called by mutect2, pindel, varscan2
- LSAMP | c.-196G>C | 5'UTR (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- MON2 | c.-363G>T | 5'UTR (SNP) | VAF 66/367 reads (18%) | called by muse, mutect2, varscan2
- NRXN1 | c.4127-4075G>C | Intron (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- PLEKHG5 | c.-15C>G | 5'UTR (SNP) | VAF 68/352 reads (19%) | catalogued as COSV66660119; called by muse, mutect2, varscan2
- PLOD2 | c.1501-1001C>A | Intron (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- RTL4 | c.*743C>A | 3'UTR (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- TMEM8B | c.819+10G>A | Intron (SNP) | VAF 118/384 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.10361-4288T>G | Intron (SNP) | VAF 50/189 reads (26%) | called by muse, mutect2, varscan2
